Somatic mutation profile of tumor specimen MMRF_2754_1_BM_CD138pos (aliquot MMRF_2754_1_BM_CD138pos_T1_KHS5U_L15085) from MMRF case MMRF_2754, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.5 years (23,920 days).
Specimen MMRF_2754_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50810ddc-e6cc-48d2-a9b8-3dc0c77f89e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2754_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2754_1_PB_WBC_C3_KHS5U_L15086; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d670109-b678-4695-bd66-6b71f328b96e

The open-access MAF lists 145 somatic variants for this specimen: 63 protein-altering or splice-affecting, 21 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 34, Silent 21, Intron 14, 5'UTR 6, RNA 4, Nonsense Mutation 3, Frame Shift Del 2, 3'Flank 2, 5'Flank 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 45/135 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2, varscan2
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 14/195 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 56/168 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 63/150 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BMX | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs774703027, COSV100564259, COSV100564556; called by muse, mutect2, varscan2
- CCDC88C | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 55/131 reads (42%) | catalogued as COSV66232037; called by muse, mutect2, varscan2
- CDC25C | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as rs762801188; called by muse, mutect2, varscan2
- CDH12 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66391037; called by muse, mutect2, varscan2
- CGN | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs373143714; called by muse, mutect2, varscan2
- CNTLN | c.250A>T p.M84L | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV52092245; called by muse, mutect2
- DCDC1 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs775180981; called by muse, mutect2, varscan2
- DSCAM | c.1797A>G p.I599M | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768712064; called by muse, mutect2
- FAM83H | c.3109C>T p.R1037W | Missense Mutation (SNP) | VAF 133/274 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100567968; called by muse, mutect2, varscan2
- FBXW7 | c.1561T>C p.F521L (on ENST00000281708 / NM_001349798.2; = p.F441L on NM_018315.5) | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.456); catalogued as COSV55947392; called by muse, mutect2, varscan2
- FMN2 | c.4364T>A p.L1455Q | Missense Mutation (SNP) | VAF 102/376 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100147754; called by muse, mutect2, varscan2
- GAD2 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs8190591; called by muse, mutect2, varscan2
- IGHV2-70 | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 27/48 reads (56%) | catalogued as rs10144402; called by muse, mutect2, varscan2
- IGLV2-14 | c.209A>T p.Y70F | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.11); catalogued as rs372979635; called by muse, mutect2, varscan2
- IGLV3-12 | c.115A>T p.I39F | Missense Mutation (SNP) | VAF 82/122 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs769516788; called by muse, varscan2
- IGLV5-45 | c.164A>C p.Y55S | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs61731374; called by muse, varscan2
- IGLV5-45 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs370576104; called by muse, varscan2
- IGLV7-46 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs553079009; called by muse, mutect2, varscan2
- PCDH18 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100786889, COSV61266628; called by muse, mutect2
- REEP6 | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 113/265 reads (43%) | catalogued as rs112200356, COSV52012770; called by muse, mutect2, varscan2
- SNW1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 101/195 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs759186141, COSV55054626; called by muse, mutect2, varscan2
- STAB1 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV58733032; called by muse, mutect2, varscan2
- TPH1 | c.35C>A p.S12Y | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV51459964; called by muse, mutect2
- TPK1 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63636842; called by muse, mutect2, varscan2
- APEX1 | c.77_82del p.S26_K27del | In Frame Del (DEL) | VAF 51/160 reads (32%) | called by mutect2, pindel, varscan2
- BEGAIN | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CRBN | c.1097G>A p.C366Y | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, varscan2
- CYLC1 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DRD3 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- GDPD1 | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GREB1L | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2
- HEPHL1 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- IFNL2 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ITGA11 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KPNA7 | c.1003C>A p.Q335K | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LCOR | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- LRGUK | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP1A | c.4876A>G p.S1626G | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- MTCL1 | c.5651G>A p.G1884E (on ENST00000306329 / NM_001378206.1; = p.G1565E on NM_015210.4) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MYH4 | c.2300T>C p.V767A | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NOP56 | c.842T>A p.L281Q | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPAS2 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCA2 | c.2348C>T p.T783I | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDP2 | c.1222G>A p.V408M | Missense Mutation (SNP) | VAF 126/291 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PLEKHN1 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- POLA2 | c.1643T>C p.V548A | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- PTPRM | c.3824T>C p.V1275A | Missense Mutation (SNP) | VAF 105/292 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PUDP | c.495del p.P166Lfs*34 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | called by mutect2, pindel, varscan2
- SALL3 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAMD4B | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SRFBP1 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SRSF7 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SSRP1 | c.1252G>T p.V418F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SVEP1 | c.5534T>C p.V1845A | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- TENT5C | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TPP2 | c.3346C>T p.Q1116* | Nonsense Mutation (SNP) | VAF 66/233 reads (28%) | called by muse, mutect2, varscan2
- ZNF292 | c.5220_5223del p.N1741Lfs*25 | Frame Shift Del (DEL) | VAF 41/95 reads (43%) | called by mutect2, pindel, varscan2
- ZNF695 | c.1415C>A p.A472D | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZSWIM8 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 60/356 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ALPK3 | c.4635C>A p.G1545= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- ANKS1B | c.2491C>T p.L831= (on ENST00000547776 / NM_152788.4; = p.L57= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/272 reads (31%) | called by muse, mutect2, varscan2
- CACNA1H | c.1098C>T p.Y366= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as rs370077125; called by muse, mutect2
- CALHM3 | c.477G>A p.E159= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as COSV63922658; called by muse, mutect2
- CAMK1 | c.1086G>A p.L362= | Silent (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- CUX2 | c.516C>T p.L172= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- DCAF1 | c.3945A>G p.A1315= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- DDR2 | c.1866T>C p.F622= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs754180676; called by muse, mutect2, varscan2
- EML3 | c.1266C>T p.V422= | Silent (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- FFAR3 | c.540C>T p.I180= | Silent (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- GPR45 | c.211C>T p.L71= | Silent (SNP) | VAF 112/296 reads (38%) | catalogued as rs957871187, COSV51525696; called by muse, mutect2, varscan2
- IGLV1-40 | c.12T>C p.S4= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as rs1199242572; called by muse, mutect2, varscan2
- IGLV7-46 | c.138A>T p.G46= | Silent (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- MAGOH | c.60G>A p.E20= | Silent (SNP) | VAF 29/379 reads (8%) | called by muse, mutect2
- MUC5AC | c.16941C>A p.G5647= | Silent (SNP) | VAF 18/171 reads (11%) | called by muse, mutect2, varscan2
- NT5DC3 | c.903C>T p.S301= | Silent (SNP) | VAF 146/351 reads (42%) | called by muse, mutect2, varscan2
- PDE7B | c.30C>T p.G10= | Silent (SNP) | VAF 47/307 reads (15%) | catalogued as rs373329929; called by muse, mutect2, varscan2
- TENM3 | c.7923C>T p.R2641= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs1314893506; called by muse, mutect2, varscan2
- TOMM70 | c.1707C>T p.N569= | Silent (SNP) | VAF 77/209 reads (37%) | catalogued as rs1234642768; called by muse, mutect2, varscan2
- UBR3 | c.3900A>G p.L1300= | Silent (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
- XKR4 | c.1794C>T p.D598= | Silent (SNP) | VAF 30/310 reads (10%) | catalogued as rs112000681; called by muse, mutect2
- ANKRD49 | c.*842T>G | 3'UTR (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
- AP2A1 | c.2114+69C>G | Intron (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- BHLHE22 | chr8:64576367 C>T | 5'Flank (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- BMP6 | c.*1335A>C | 3'UTR (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- BVES | c.*3655C>A | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- C7 | c.2075-54T>C | Intron (SNP) | VAF 52/129 reads (40%) | called by muse, mutect2, varscan2
- CALM2 | c.*603A>G | 3'UTR (SNP) | VAF 39/81 reads (48%) | catalogued as rs1316459824; called by muse, mutect2, varscan2
- CCDC117 | c.*2020G>C | 3'UTR (SNP) | VAF 18/86 reads (21%) | called by mutect2, varscan2
- CDS1 | c.-176T>A | 5'UTR (SNP) | VAF 45/116 reads (39%) | called by muse, mutect2, varscan2
- CPSF4 | c.*202G>A | 3'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- CRABP2 | c.*243G>A | 3'UTR (SNP) | VAF 17/120 reads (14%) | catalogued as rs1010363230; called by muse, mutect2, varscan2
- CT867976.1 | n.373_374dup | RNA (INS) | VAF 3/29 reads (10%) | catalogued as rs1374952990; called by mutect2*, pindel
- CYB5R3 | c.*1567A>C | 3'UTR (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
- DDX18 | c.*582A>T | 3'UTR (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- DENND11 | c.*3896C>A | 3'UTR (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- DNAJA2 | c.775-26G>A | Intron (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- ENAH | c.*2641A>G | 3'UTR (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- EPHA7 | c.*1020C>T | 3'UTR (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- EPHX1 | c.364+133G>A | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as rs951228024; called by muse, mutect2
- FCHSD2 | c.*907T>C | 3'UTR (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- FGF5 | c.*3413C>A | 3'UTR (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2, varscan2
- FOXK1 | c.*7374C>G | 3'UTR (SNP) | VAF 7/83 reads (8%) | catalogued as rs897607393; called by muse, mutect2
- FSHB | c.*485G>A | 3'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- GPCPD1 | c.*1398T>G | 3'UTR (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- GPRC5A | c.*5134C>T | 3'UTR (SNP) | VAF 58/164 reads (35%) | called by muse, mutect2, varscan2
- GVINP1 | n.5316T>A | RNA (SNP) | VAF 83/209 reads (40%) | called by muse, mutect2, varscan2
- HERC2 | c.12409-61C>T | Intron (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- IGLV1-41 | n.272G>C | RNA (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- KCNJ1 | c.*284T>C | 3'UTR (SNP) | VAF 9/76 reads (12%) | catalogued as COSV60662399; called by muse, mutect2, varscan2
- KCTD8 | c.-200C>A | 5'UTR (SNP) | VAF 7/59 reads (12%) | catalogued as rs1170547798; called by muse, varscan2
- KLRC4 | c.-164G>A | 5'UTR (SNP) | VAF 10/151 reads (7%) | called by muse, mutect2
- LACTB | c.*43T>G | 3'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- LCP1 | c.*196C>T | 3'UTR (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- LINC02538 | n.1806G>A | RNA (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- MARVELD2 | c.*934A>C | 3'UTR (SNP) | VAF 109/224 reads (49%) | called by muse, mutect2, varscan2
- MEIS2 | c.*1391T>C | 3'UTR (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- NKAIN2 | c.-113C>T | 5'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- NKX2-1 | chr14:36513551 G>T | 3'Flank (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- NNT | c.*1738C>T | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- NT5C3B | c.12+25G>T | Intron (SNP) | VAF 47/93 reads (51%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*1407C>T | 3'UTR (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- PSMD11 | c.*614G>A | 3'UTR (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- RNASE7 | c.*262G>A | 3'UTR (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2
- SESN3 | c.*2918C>T | 3'UTR (SNP) | VAF 6/79 reads (8%) | catalogued as rs1237673437; called by muse, mutect2
- SLC25A2 | c.-84C>T | 5'UTR (SNP) | VAF 11/252 reads (4%) | called by muse, mutect2
- SLC27A3 | c.1420+75T>A | Intron (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- SLMAP | c.2022+1057T>G | Intron (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- SNX13 | c.*58C>A | 3'UTR (SNP) | VAF 31/275 reads (11%) | called by muse, mutect2, varscan2
- STEAP4 | c.984+593G>T | Intron (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- SYNJ2BP | c.*331G>T | 3'UTR (SNP) | VAF 13/94 reads (14%) | catalogued as COSV99832586; called by muse, mutect2, varscan2
- TBC1D30 | c.*309C>T | 3'UTR (SNP) | VAF 37/79 reads (47%) | catalogued as rs1006860199; called by muse, mutect2, varscan2
- TFAP4 | c.666+13C>T | Intron (SNP) | VAF 9/88 reads (10%) | catalogued as rs761671551; called by muse, mutect2, varscan2
- TFDP2 | c.*1063T>C | 3'UTR (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- THRA | c.1110+63G>T | Intron (SNP) | VAF 14/298 reads (5%) | called by muse, mutect2
- TIAL1 | chr10:119574858 del GTA | 3'Flank (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- TOX3 | c.907-27G>C | Intron (SNP) | VAF 45/132 reads (34%) | called by muse, mutect2, varscan2
- TPRA1 | c.-830G>C | 5'UTR (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- TRIM36 | c.*1432C>G | 3'UTR (SNP) | VAF 59/129 reads (46%) | called by muse, mutect2, varscan2
- UBA5 | c.161+13G>A | Intron (SNP) | VAF 72/167 reads (43%) | called by muse, mutect2, varscan2
- XDH | c.*229G>A | 3'UTR (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- ZNF726 | c.130+98T>C | Intron (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
